HCMI case HCM-CSHL-0863-C18 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Colon. Index date (day 0 for every day count below): first patient visit.
https://portal.gdc.cancer.gov/cases/80662c9b-a131-4e8e-8622-07eca4e1127b

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Days to birth: -15,397 days (42.2 years before the index date); Year of birth: 1978; Vital status: Alive.

Diagnoses (2)
1. Mucinous adenocarcinoma (the primary disease): ICD-O-3 morphology code: 8480/3; ICD-10 code: C18.9; Tissue or organ of origin: Colon, NOS; Classification of tumor: primary; AJCC pathologic T: TX; AJCC pathologic N: NX; AJCC pathologic M: M0; Tumor grade: GX; Prior malignancy: no; Synchronous malignancy: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 29 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease.
   Recorded as not given: adjuvant Chemotherapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.
2. Carcinoma, metastatic, NOS: ICD-O-3 morphology code: 8010/6; ICD-10 code: C79.71; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Adrenal gland, NOS; Classification of tumor: metastasis; Days to diagnosis: 17 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Bevacizumab; Treatment intent type: Maintenance Therapy; Days to treatment end: 45 days.

Follow-up (2 entries)
- Days to follow up: 232 days; Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 29.

Molecular and laboratory tests
- BRAF (IHC): Negative.
- BRAF mutation, nos: Negative.
- CEA: 2.5 ng/mL.
- KRAS mutation, nos: Positive; Amino-acid change: p.Gly13Asp.
- Test (Microsatellite Analysis): Positive.
- Test (Sequencing, NOS): Positive; Mismatch repair mutation: Yes.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 56.2 kg; Height: 170.2 cm; BMI: 19.
- Timepoint category: Prior to Diagnosis; Risk factors: Lynch Syndrome / Diabetes, Type II.

Exposures
- Tobacco smoking status: Current Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Colorectal Cancer.

Biospecimens (2 samples)
- Sample HCM-CSHL-0863-C18-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-CSHL-0863-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
